Somatic mutation profile of tumor specimen TCGA-E3-A3DZ-01A (aliquot TCGA-E3-A3DZ-01A-11D-A20C-08) from TCGA case TCGA-E3-A3DZ, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 55.4 years (20,251 days).
Specimen TCGA-E3-A3DZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f2897ce2-99c6-42f9-9c91-708de7e9abda.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-E3-A3DZ-10A (Blood Derived Normal), aliquot TCGA-E3-A3DZ-10A-01D-A20C-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8136a145-4abc-4f55-9f52-a6e4f7089ab2

The open-access MAF lists 17 somatic variants for this specimen: 14 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 2, 3'UTR 1, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 91/230 reads (40%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen benign (0.067); catalogued as rs28933406, COSV54236740, COSV54240324, COSV54242140; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ATP1B4 | c.236G>A p.G79D | Missense Mutation (SNP) | VAF 51/109 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs867599281, COSV54313306; called by muse, mutect2, varscan2
- DCAF13 | c.730A>G p.I244V | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT tolerated (0.2); PolyPhen benign (0.011); catalogued as rs999376459, COSV52572650; called by muse, mutect2, varscan2
- FAM13A | c.1340A>T p.Q447L | Missense Mutation (SNP) | VAF 41/131 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.023); catalogued as COSV52005258; called by muse, mutect2, varscan2
- FAM76B | c.26G>C p.C9S | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57689090; called by muse, mutect2, varscan2
- GCC2 | c.1726A>T p.S576C | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.43); catalogued as COSV59177438; called by muse, mutect2, varscan2
- MARCHF1 | c.362G>A p.R121H (on ENST00000274056; = p.R104H on NM_017923.4) | Missense Mutation (SNP) | VAF 45/180 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs753428751, COSV56819512; called by muse, mutect2, varscan2
- MID2 | c.1523G>A p.R508H | Missense Mutation (SNP) | VAF 6/142 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as rs866967372, COSV53311161; called by muse, mutect2
- OTUD6A | c.631G>T p.V211L | Missense Mutation (SNP) | VAF 42/105 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.756); catalogued as COSV57972732, COSV57973745; called by muse, mutect2, varscan2
- SPAG17 | c.4065G>C p.K1355N | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as COSV60461445, COSV60464445; called by muse, mutect2, varscan2
- ZNF211 | c.1561A>G p.S521G (on ENST00000347302 / NM_198855.4; = p.S534G on NM_006385.5) | Missense Mutation (SNP) | VAF 7/205 reads (3%) | SIFT tolerated (0.15); PolyPhen benign (0.017); catalogued as COSV53743136, COSV99560038; called by muse, mutect2
- ZNF692 | c.379A>C p.S127R | Missense Mutation (SNP) | VAF 73/176 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV60659664; called by muse, mutect2, varscan2
- HERC1 | c.14505del p.N4835Kfs*41 | Frame Shift Del (DEL) | VAF 17/45 reads (38%) | called by mutect2, pindel, varscan2
- TMEM62 | c.1146_1148del p.S384del | In Frame Del (DEL) | VAF 15/40 reads (38%) | called by mutect2, pindel, varscan2
- COBL | c.3603G>A p.L1201= | Silent (SNP) | VAF 36/94 reads (38%) | catalogued as COSV54349022; called by muse, mutect2, varscan2
- ZNF33B | c.1284C>T p.L428= | Silent (SNP) | VAF 70/173 reads (40%) | catalogued as COSV63942782; called by muse, mutect2, varscan2
- CDKN1B | c.*70T>G | 3'UTR (SNP) | VAF 5/16 reads (31%) | catalogued as COSV99963781; called by muse, mutect2, varscan2
